Somatic mutation profile of tumor specimen TCGA-MH-A854-01A (aliquot TCGA-MH-A854-01A-11D-A34Z-10) from TCGA case TCGA-MH-A854, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.4 years (22,804 days).
Specimen TCGA-MH-A854-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1634e2b-d26c-46c7-89da-7bb655fdd3a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A854-10A (Blood Derived Normal), aliquot TCGA-MH-A854-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29e94cbb-066c-467b-91dd-db76c636a7c7

The open-access MAF lists 128 somatic variants for this specimen: 105 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 88, Silent 23, Frame Shift Del 12, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 124/190 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.1718T>C p.L573P (on ENST00000372530 / NM_001198934.2; = p.L530P on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99766749; called by muse, mutect2, varscan2
- ADD1 | c.1559A>T p.Q520L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99296037; called by muse, mutect2, varscan2
- AGTRAP | c.239G>A p.S80N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100065179; called by muse, mutect2, varscan2
- ALPI | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55016396; called by muse, varscan2
- ANK3 | c.4306C>G p.L1436V (on ENST00000280772 / NM_001320874.2; = p.L570V on NM_001149.3) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99778452; called by muse, mutect2, varscan2
- ARFGEF2 | c.419T>G p.I140S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100903998; called by muse, mutect2, varscan2
- B3GAT3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs374687580, COSV99641818; called by muse, mutect2, varscan2
- BRPF3 | c.2618A>G p.K873R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100325572; called by muse, mutect2, varscan2
- C8B | c.1177T>A p.Y393N | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV100980698; called by muse, mutect2, varscan2
- CABIN1 | c.3116A>T p.E1039V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99572744; called by muse, mutect2, varscan2
- CACNA2D2 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748093850, COSV99816932; called by muse, mutect2, varscan2
- CACNA2D4 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV99765076; called by muse, mutect2, varscan2
- CHAMP1 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV100778726; called by muse, mutect2, varscan2
- COL5A1 | c.4333C>T p.P1445S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs757989702, COSV100879553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCR6 | c.886C>G p.R296G | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99945174; called by muse, mutect2, varscan2
- DBP | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99320503; called by muse, mutect2, varscan2
- DDX20 | c.338C>G p.T113S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747625817, COSV100865893; called by muse, mutect2, varscan2
- DMTF1 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV100487254; called by muse, mutect2, varscan2
- DNAJB6 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100055304; called by muse, mutect2, varscan2
- EPB41L2 | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as COSV100440248; called by muse, mutect2, varscan2
- EPG5 | c.7271T>G p.V2424G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99956553; called by muse, mutect2, varscan2
- ETNK2 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs377403947; called by muse, mutect2, varscan2
- ETNK2 | c.457T>C p.Y153H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100916654; called by muse, mutect2, varscan2
- EYA4 | c.1901T>C p.L634P (on ENST00000531901 / NM_001301013.1; = p.L628P on NM_004100.5) | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV100765216; called by muse, mutect2, varscan2
- FAM124A | c.253C>T p.R85W (on ENST00000322475 / NM_001242312.2; = p.R121W on NM_145019.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54478312; called by muse, mutect2, varscan2
- FAM47A | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1200250652, COSV60497293; called by muse, mutect2, varscan2
- FITM2 | c.401A>T p.H134L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV101201978; called by muse, mutect2, varscan2
- GBF1 | c.2372G>A p.R791H (on ENST00000369983 / NM_001377137.1; = p.R790H on NM_004193.3) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246149215, COSV100890330; called by muse, mutect2, varscan2
- GKN1 | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750375287, COSV100933538; called by muse, mutect2, varscan2
- GPR162 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs868975551, COSV50595402; called by muse, mutect2, varscan2
- GREB1 | c.2894A>G p.E965G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52185939; called by muse, mutect2, varscan2
- GTF3C1 | c.4841A>G p.D1614G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV62242501; called by muse, mutect2, varscan2
- HCAR2 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100186429; called by muse, mutect2, varscan2
- HNRNPUL1 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99646920; called by muse, mutect2, varscan2
- HSPA13 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.185); catalogued as rs1225759340, COSV99579894; called by muse, mutect2, varscan2
- IKBKG | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.325); catalogued as COSV100852985; called by muse, mutect2, varscan2
- INO80B | c.116A>T p.K39I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99270314; called by muse, mutect2
- KDM2B | c.2303G>A p.S768N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100997211; called by muse, mutect2, varscan2
- KDM3A | c.2549T>G p.I850S | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100460029; called by muse, mutect2, varscan2
- KLF4 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV101012647; called by muse, mutect2
- KPNA5 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100706097; called by muse, mutect2, varscan2
- KRT83 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs1250301217, COSV53339924; called by muse, mutect2, varscan2
- LSM5 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764519400, COSV99776369; called by muse, mutect2, varscan2
- MED12 | c.4966T>G p.S1656A | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV100376261; called by muse, mutect2, varscan2
- MGAT4B | c.1440G>T p.K480N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.264); catalogued as COSV99482055; called by muse, mutect2, varscan2
- MUC16 | c.12512C>G p.P4171R | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV101198281; called by muse, mutect2, varscan2
- NAXD | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100010309, COSV59396332; called by muse, mutect2, varscan2
- NCAPD2 | c.3941C>A p.P1314Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57520423; called by muse, mutect2, varscan2
- NEUROD2 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223089; called by muse, mutect2, varscan2
- NLGN2 | c.637A>C p.N213H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100259276; called by muse, mutect2, varscan2
- OVGP1 | c.2024A>G p.D675G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV100868013; called by muse, mutect2, varscan2
- PARP1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs779486158, COSV100828781; called by muse, mutect2, varscan2
- PCLO | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100427692; called by muse, mutect2, varscan2
- PIK3C2B | c.3508T>A p.Y1170N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915990; called by muse, mutect2, varscan2
- PNPLA1 | c.338A>G p.Y113C (on ENST00000394571 / NM_001374623.1; = p.Y18C on NM_173676.2) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100462671; called by muse, mutect2, varscan2
- POLD1 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs1060501824, COSV99569785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPM1M | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99626033; called by muse, mutect2, varscan2
- PPP1R2 | c.283A>G p.M95V | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs779600058, COSV100113288; called by muse, mutect2, varscan2
- PSMC2 | c.1135A>T p.N379Y | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99485157; called by muse, mutect2, varscan2
- PSMC3 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as COSV100099309; called by muse, mutect2, varscan2
- PTGFRN | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as COSV101277248; called by muse, mutect2, varscan2
- REV3L | c.6973T>C p.F2325L | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100724893; called by muse, mutect2, varscan2
- RFX1 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99585804; called by muse, mutect2, varscan2
- RFX6 | c.1724T>C p.L575P | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100263277, COSV60587803; called by muse, mutect2, varscan2
- S100A16 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.962); catalogued as COSV100905873, COSV64183047; called by muse, mutect2, varscan2
- SASH3 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63555597; called by muse, mutect2, varscan2
- SETDB1 | c.1581A>T p.R527S | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99643825; called by muse, mutect2, varscan2
- SH3TC2 | c.2205G>T p.L735F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100101237; called by muse, mutect2, varscan2
- SLC12A9 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs754019847, COSV99307494; called by muse, mutect2, varscan2
- SLC19A2 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99356810; called by muse, mutect2, varscan2
- SLC25A32 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756664081, COSV52567478; called by muse, mutect2, varscan2
- SMAD9 | c.1042G>A p.E348K (on ENST00000379826 / NM_001127217.3; = p.E311K on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs375386551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPD1 | c.1073A>G p.E358G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV100192369; called by muse, mutect2, varscan2
- SMTN | c.1397A>C p.K466T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100293998; called by muse, mutect2, varscan2
- SPTLC1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.414); catalogued as COSV99364536; called by muse, mutect2, varscan2
- STEAP4 | c.1044T>G p.Y348* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | catalogued as COSV100112396, COSV57327827; called by muse, mutect2, varscan2
- SZT2 | c.3718T>C p.Y1240H (on ENST00000634258 / NM_001365999.1; = p.Y1183H on NM_015284.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs765996086, COSV100986900; called by muse, mutect2, varscan2
- TCF12 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV99976392; called by muse, mutect2
- THSD7A | c.1750T>C p.C584R | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448552; called by muse, mutect2, varscan2
- UBR3 | c.5297G>A p.C1766Y | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99773256; called by muse, mutect2, varscan2
- USH2A | c.15268A>C p.N5090H | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs777779953, COSV100229451; called by muse, mutect2, varscan2
- VARS2 | c.1022C>G p.T341R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99461493; called by muse, mutect2, varscan2
- WDR44 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV99561210; called by muse, varscan2
- XIRP1 | c.3961A>C p.K1321Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100453412; called by muse, mutect2, varscan2
- ZBTB10 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100990085; called by muse, mutect2, varscan2
- ZNF639 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs75079502, COSV100418382; called by muse, mutect2, varscan2
- ZNF644 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV100494275; called by muse, mutect2, varscan2
- AGPAT5 | c.443del p.N148Tfs*22 | Frame Shift Del (DEL) | VAF 108/286 reads (38%) | called by mutect2, pindel, varscan2
- CEP162 | c.13del p.S5Pfs*5 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- CLASRP | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); called by muse, mutect2
- CLIC6 | c.1626_1627del p.K542Nfs*25 (on ENST00000360731 / NM_001317009.2; = p.K524Nfs*25 on NM_053277.3) | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- KYAT3 | c.1195_1196delinsT p.K399Yfs*3 | Frame Shift Del (DEL) | VAF 71/247 reads (29%) | called by pindel, varscan2*
- MT1H | c.115dup p.L39Pfs*37 | Frame Shift Ins (INS) | VAF 50/121 reads (41%) | called by mutect2, pindel, varscan2
- MYF6 | c.507del p.K170Nfs*29 | Frame Shift Del (DEL) | VAF 11/18 reads (61%) | called by mutect2, varscan2
- NOX3 | c.20del p.L7* | Frame Shift Del (DEL) | VAF 68/148 reads (46%) | called by mutect2, pindel, varscan2
- PAPSS2 | c.587dup p.L196Ffs*6 | Frame Shift Ins (INS) | VAF 26/91 reads (29%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 152/451 reads (34%) | called by muse, varscan2
- SEPHS2 | c.295_311delinsA p.E99Kfs*? | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by pindel, varscan2*
- TAF3 | c.668del p.K223Rfs*41 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | called by mutect2, pindel, varscan2
- TFR2 | c.66_75del p.Y23Wfs*31 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, pindel, varscan2
- TMEM131 | c.5250_5256del p.S1751Gfs*157 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- TUBGCP6 | c.4706G>T p.S1569I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR44 | c.402del p.E134Dfs*2 | Frame Shift Del (DEL) | VAF 58/148 reads (39%) | called by pindel, varscan2
- ZNF749 | c.2205del p.K735Nfs*37 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- ADCY5 | c.2229C>T p.T743= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100567338; called by muse, mutect2, varscan2
- ALPL | c.519C>A p.T173= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100876789; called by muse, mutect2, varscan2
- ALS2 | c.930T>A p.A310= | Silent (SNP) | VAF 101/231 reads (44%) | catalogued as COSV99968797; called by muse, mutect2, varscan2
- ANO8 | c.2299C>T p.L767= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs1446262892, COSV99344083; called by muse, mutect2, varscan2
- AQP3 | c.61C>T p.L21= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV99955496; called by muse, mutect2, varscan2
- ARL8B | c.417T>C p.D139= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV99848493; called by muse, mutect2, varscan2
- CCDC186 | c.540A>C p.V180= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as COSV100990988; called by muse, mutect2, varscan2
- CLCN7 | c.726G>A p.L242= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs773054717, COSV99246912; called by muse, varscan2
- EPHA5 | c.2712T>C p.P904= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs759612873, COSV99896400; called by muse, mutect2, varscan2
- FKRP | c.1389C>T p.N463= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs765591278, COSV100586648; called by muse, mutect2, varscan2
- LRRC32 | c.1485C>T p.V495= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV99476702; called by muse, mutect2, varscan2
- NIPAL1 | c.675G>A p.L225= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV55007566, COSV99784302; called by muse, mutect2, varscan2
- NIT2 | c.810T>A p.A270= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV101237074; called by muse, mutect2, varscan2
- OBSCN | c.5358C>T p.S1786= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs374335072; called by muse, mutect2, varscan2
- SIGLEC1 | c.3162C>A p.I1054= | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as rs1458586829, COSV52460430, COSV99163340; called by muse, mutect2, varscan2
- SLC22A2 | c.1263A>G p.S421= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100870927; called by muse, mutect2, varscan2
- SLC38A3 | c.612G>C p.L204= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs779247653, COSV101309860; called by muse, mutect2, varscan2
- SPTLC2 | c.1152T>C p.S384= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs748828910, COSV99377220; called by muse, mutect2, varscan2
- STAB1 | c.3516C>T p.S1172= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs780733710, COSV100401248; called by muse, mutect2, varscan2
- TSC2 | c.114T>C p.F38= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1060504110, CD090959, COSV99526117; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBTF | c.1068G>T p.V356= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100255790; called by muse, mutect2, varscan2
- XPO4 | c.2664G>C p.V888= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV99688072; called by muse, mutect2, varscan2
- ZNF74 | c.75T>C p.N25= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100677424; called by muse, mutect2, varscan2
